Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8CH, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8CH-01A (Primary Tumor).

[page 1 of 3]
Pathology Surgical Pathology Request

Temporary Copy

Page 1 of 2

Case#

Collected

Ordered by

Patient

IC

Location

ACCESSION

Submitting Physician

Clinical History

This woman presents with a one year history of generalized tonic/clonic seizures. Imaging studies reveal a nonenhancing right frontal tumor.

Diagnosis

BRAIN, RIGHT FRONTAL TUMOR, RESECTION : DIFFUSE ASTROCYTOMA, WHO GRADE II (SEE COMMENTS).

I certify that I personally conducted the diagnostic evaluation on the above specimens and have rendered the above diagnosis(es):

electronic signature

Department of Pathology

ICD-O-3

Astrocytoma, grade II
940013

Site
C6E Brain, supratentorial NOS
path B Brain, frontal lobe
C71.0
C71.1
JW 11/27/13

For questions regarding this case, call

Comments

Sections of this tumor are referred for a PCR-based MGMT methylation assay. These results will be reported in an addendum when available.

Gross Description

Received in formalin is a specimen labeled with the patient's name, medical record number and "#1 right frontal lobe tumor." It consists of 3.39 grams of tissue measuring 2.2 x 1.5 x 1.4 cm in aggregate. Representative sections are submitted in cassettes 1A-1B and the remaining tissue is returned to formalin.

Microscopic Examination

Sections reveal an edematous glial, infiltrating tumor of astrocytic lineage. The neoplasm is moderately hypercellular and contains mildly pleomorphic, hyperchromatic nuclei. No mitoses are seen in 40 HPF and microvascular proliferation is absent. Necrosis is not identified.

Immunohistochemistry for glial fibrillary acidic protein is diffusely positive in the neoplasm. MIB-1 is focally elevated at 20%. IDH-1 is negative in the tumor, therefore, the tumor is unlikely to be mutated for IDH-1. p53 immunostaining is diffusely positive. All controls are appropriate.

This test was developed and its performance characteristics determined by

The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use. The results are not intended to be used as the sole means for clinical diagnosis or patient management decisions.

[page 2 of 3]
Pathology Surgical Pathology Request

Temporary Copy

Page 2 of 2

Case:

Collected:

Ordered by:

Patient:

Location:

Synoptic Report

Specimen type/procedure: Resection.

Specimen handling: Permanent Sections.

Laterality: Right.

Tumor site: Frontal lobe.

Histologic type and grade: Diffuse astrocytoma, WHO Grade II.

Histologic Grade: WHO Grade II.

Margins: Cannot be assessed.

[page 3 of 3]
Addendum Report

Temporary Copy

Page 1 of 1

Case#

Patient

Collected

Ordered by

Location

ACCESSION

Addendum Discussion

MGMT METHYLATION ASSAY : GENE METHYLATION NOT DETECTED.

MGMT Methylation Assay was performed on sections from block "1B" by in
The results of this assay are reported below:

MGMT Methylation Assay:

Result: Gene Methylation NOT detected.
Methylation Score: 1.35

--REFERENCE VALUE--
unmethylated <2.00
methylated >=2.00

Background:

MGMT [O(6)-methylguanine-DNA methyltransferase] is a DNA repair enzyme that is involved in the repair of damage caused by a variety of DNA crosslinking compounds, including alkylating agents. Increased methylation of the MGMT gene promotor region causes diminished or silenced expression of the gene, making cells more sensitive to DNA damage. This relationship has been shown for glioblastomas and alkylating agents such as temozolomide. Approximately 40-50% of glioblastomas exhibit MGMT gene methylation. Retrospective studies have shown that detection of MGMT promotor methylation in tumor samples is associated with an increased likelihood of a favorable response to temozolomide.

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimens. Molecular analysis of the MGMT gene is performed by methylation-specific PCR and detected on ABI7900. The MGMT and beta-Actin copy numbers are used to calculate the ratio of MGMT/beta-Actin x1000. Molecular-based testing is highly accurate, but as in any laboratory test, rare diagnostic errors may occur. Results of this test are for Investigational Purposes Only. The performance characteristics of this assay have been determined by The result should not be used as a diagnostic procedure without confirmation of the diagnosis by another medically established diagnostic product or procedure.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

IHPAA Discrepancy		
Reviewer Initials	BCR	Co.e Reviewed 10/24/13

Source: NCI Genomic Data Commons file 92a7315a-6877-4c42-ad8d-9a69119e055e (TCGA-VM-A8CH.A289AB8D-8051-48E9-91FE-0420ED724E93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).